Somatic mutation profile of tumor specimen MMRF_2497_1_BM_CD138pos (aliquot MMRF_2497_1_BM_CD138pos_T1_KHS5U_K15191) from MMRF case MMRF_2497, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.1 years (25,622 days).
Specimen MMRF_2497_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a25351d2-2186-4434-a63a-832391b301bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2497_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2497_1_PB_Whole_C3_KHS5U_K15192; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a28f91f-c79b-46d0-95a0-dd9ce9230400

The open-access MAF lists 106 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 36, Missense Mutation 29, Intron 13, Silent 9, Frame Shift Del 4, 5'UTR 3, RNA 3, 3'Flank 2, 5'Flank 2, Nonsense Mutation 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.1687G>A p.D563N (on ENST00000326724 / NM_001080395.3; = p.D460N on NM_004920.2) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58366261; called by muse, mutect2
- ABCC1 | c.1914C>T p.G638= | Splice Region (SNP) | VAF 40/101 reads (40%) | catalogued as rs768571544; called by muse, mutect2, varscan2
- CNOT1 | c.4156C>T p.H1386Y | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs1193225392, COSV99800558; called by muse, mutect2, varscan2
- DCDC2B | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1215972976; called by muse, mutect2, varscan2
- DCLK1 | c.2101C>T p.R701C (on ENST00000360631 / NM_001330072.2; = p.D725= on NM_004734.5) | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV55189268; called by muse, mutect2, varscan2
- FAM50B | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 112/230 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1417263642, COSV66654608; called by muse, mutect2, varscan2
- FAT1 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.214); catalogued as rs765982067, COSV101499087; called by muse, mutect2, varscan2
- KATNAL1 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs929151300; called by muse, mutect2, varscan2
- MYH13 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760092709, COSV99355533; called by muse, varscan2
- OR4P4 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1296670777; called by muse, mutect2, varscan2
- TNS3 | c.3692A>G p.N1231S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs202130688; called by muse, mutect2, varscan2
- USH1C | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50015844; called by muse, mutect2, varscan2
- ZC3H15 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.206); catalogued as rs1487754557; called by muse, mutect2, varscan2
- ACKR1 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ASH1L | c.3858_3860del p.F1287del | In Frame Del (DEL) | VAF 49/236 reads (21%) | called by mutect2, pindel, varscan2
- ATF3 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETHE1 | c.683A>C p.N228T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GAL3ST1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- GOLGA4 | c.2005del p.E669Kfs*3 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- IFT52 | c.36T>A p.N12K | Missense Mutation (SNP) | VAF 139/290 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IQCH | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- KDM5C | c.943_962del p.N315Yfs*2 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- LAMA1 | c.6939T>A p.S2313R | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- MGA | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MN1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCALD | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PADI2 | c.628_631del p.D210Kfs*72 | Frame Shift Del (DEL) | VAF 36/78 reads (46%) | called by mutect2, pindel, varscan2
- PNPLA3 | c.542C>G p.T181S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF123 | c.3335C>G p.A1112G | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- RNF133 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3E | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- SLC7A9 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SMARCA2 | c.1786A>T p.K596* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- SYNPR | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1624_1625del p.V542Sfs*8 | Frame Shift Del (DEL) | VAF 61/91 reads (67%) | called by mutect2, pindel, varscan2
- TRIM62 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF729 | c.382dup p.S128Kfs*4 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- B3GAT1 | c.955C>T p.L319= | Silent (SNP) | VAF 41/286 reads (14%) | catalogued as COSV56994979; called by muse, mutect2, varscan2
- DMPK | c.516G>A p.A172= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs748808453, COSV99353672; called by muse, mutect2, varscan2
- EGR1 | c.118C>T p.L40= | Silent (SNP) | VAF 126/236 reads (53%) | called by muse, mutect2, varscan2
- MCF2 | c.2592C>G p.V864= | Silent (SNP) | VAF 6/143 reads (4%) | catalogued as COSV100644974; called by muse, mutect2
- OR56B1 | c.24C>G p.L8= | Silent (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2
- PER1 | c.3714G>A p.Q1238= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs377443829; called by muse, mutect2, varscan2
- SLC49A3 | c.1383C>T p.N461= (on ENST00000404286 / NM_001294341.2; = p.N460= on NM_032219.4) | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs758247228, COSV59140131; called by muse, mutect2, varscan2
- UNC5D | c.1374C>A p.I458= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as COSV54774132; called by muse, mutect2, varscan2
- XKR6 | c.525G>A p.L175= | Silent (SNP) | VAF 63/369 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.*108G>A | 3'UTR (SNP) | VAF 45/90 reads (50%) | catalogued as rs1321021056; called by muse, mutect2, varscan2
- ANKRD33 | chr12:51888028 C>T | 5'Flank (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- BNIPL | c.*302C>T | 3'UTR (SNP) | VAF 14/66 reads (21%) | catalogued as rs1424276650; called by muse, mutect2, varscan2
- BRSK2 | c.91+21096C>T | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs1411657693; called by muse, mutect2
- C8orf34-AS1 | n.1249A>C | RNA (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- CALN1 | c.*2453C>A | 3'UTR (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- CBLN3 | c.*549A>T | 3'UTR (SNP) | VAF 73/121 reads (60%) | called by muse, mutect2, varscan2
- CCL14 | c.79+789A>G | Intron (SNP) | VAF 104/210 reads (50%) | catalogued as rs1408004108; called by muse, mutect2, varscan2
- CCL22 | c.*1179C>G | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- CCZ1 | c.780+28A>G | Intron (SNP) | VAF 109/191 reads (57%) | catalogued as rs769771634; called by muse, mutect2, varscan2
- CEPT1 | c.*577T>G | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- CLDN4 | chr7:73829838 G>T | 5'Flank (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- CLN3 | c.47-16C>T | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- COL24A1 | c.*503C>G | 3'UTR (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- DPH1 | c.907-48T>C | Intron (SNP) | VAF 92/225 reads (41%) | called by muse, mutect2, varscan2
- ECE1 | c.*43G>A | 3'UTR (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- EIF2B1 | c.*335C>T | 3'UTR (SNP) | VAF 38/76 reads (50%) | catalogued as rs1374088515; called by muse, mutect2, varscan2
- FAM87A | n.1953G>A | RNA (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- FBXO46 | c.*543C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- FOXB1 | c.*9A>G | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- GCK | c.1020-160A>G | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- HOXD12 | c.574+24G>C | Intron (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- HPS4 | c.*438C>T | 3'UTR (SNP) | VAF 78/181 reads (43%) | catalogued as rs899956428; called by muse, mutect2, varscan2
- IAPP | c.*856C>T | 3'UTR (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- ICAM3 | chr19:10333750 C>T | 3'Flank (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- IGLL5 | c.-215A>C | 5'UTR (SNP) | VAF 34/63 reads (54%) | catalogued as COSV104440326, COSV73249680; called by muse, mutect2, varscan2
- IP6K1 | c.*1009G>C | 3'UTR (SNP) | VAF 50/236 reads (21%) | catalogued as rs1052890013; called by muse, mutect2, varscan2
- JAG1 | c.82-19C>G | Intron (SNP) | VAF 136/245 reads (56%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.88+829G>C | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- KRTAP4-1 | c.*88G>T | 3'UTR (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- LINC02872 | n.2916G>A | RNA (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- LONRF2 | c.*6934G>C | 3'UTR (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- NCAM1 | c.1826-2688A>G | Intron (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- NDST3 | c.*1371A>C | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- NEUROG2 | c.*1042G>A | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- NKAIN2 | c.*1356A>C | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- NTRK3 | c.*13692C>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- PCDH7 | c.*84C>T | 3'UTR (SNP) | VAF 12/338 reads (4%) | catalogued as rs1446372817, COSV100687337; called by muse, mutect2
- PDE10A | c.*5414T>A | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- PDSS2 | c.*534A>T | 3'UTR (SNP) | VAF 12/52 reads (23%) | catalogued as rs542730317, COSV64655437; called by muse, varscan2
- PER3 | c.3372-77A>T | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- PLGRKT | c.*51A>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs760423408, COSV56352364; called by muse, mutect2, varscan2
- RAB22A | c.*6292T>G | 3'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- RAB22A | c.*6389T>G | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- RABEP1 | c.-133C>T | 5'UTR (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- RTL10 | c.*3749C>A | 3'UTR (SNP) | VAF 29/137 reads (21%) | called by muse, mutect2, varscan2
- SASH1 | c.*1642A>C | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- SESN3 | c.*1669T>G | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- SETD7 | c.*5065A>G | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- SH3GL2 | c.*943A>T | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*2787C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs1194431105; called by muse, mutect2, varscan2
- TAPBP | c.-9C>T | 5'UTR (SNP) | VAF 8/109 reads (7%) | catalogued as rs1171131413; called by muse, mutect2
- TARS2 | c.387+183C>T | Intron (SNP) | VAF 99/179 reads (55%) | catalogued as rs1005620832; called by muse, mutect2, varscan2
- TBC1D15 | c.*3306A>T | 3'UTR (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- TIAM2 | chr6:155257302 C>T | 3'Flank (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- TRARG1 | c.*2709A>T | 3'UTR (SNP) | VAF 36/184 reads (20%) | called by muse, mutect2, varscan2
- TUSC3 | c.*989A>T | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- ZNF195 | c.226+2187A>T | Intron (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- ZNF641 | c.*830C>T | 3'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
